Somatic mutation profile of tumor specimen TCGA-B5-A0JV-01A (aliquot TCGA-B5-A0JV-01A-11D-A10B-09) from TCGA case TCGA-B5-A0JV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.8 years (23,295 days).
Specimen TCGA-B5-A0JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c11b9af6-7f28-443f-9071-dae36812b877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JV-10A (Blood Derived Normal), aliquot TCGA-B5-A0JV-10A-01W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f971bcd1-8c1a-49b7-93e1-21eb0babe2a3

The open-access MAF lists 404 somatic variants for this specimen: 315 protein-altering or splice-affecting, 84 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 84, Frame Shift Del 65, Nonsense Mutation 18, Frame Shift Ins 12, Splice Site 4, 5'UTR 2, Intron 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 96/213 reads (45%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- ATM | c.5712dup p.S1905Ifs*25 | Frame Shift Ins (INS) | VAF 88/522 reads (17%) | catalogued as rs587781730; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 18/410 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/342 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 50/267 reads (19%) | catalogued as rs761525156, CM050686, COSV51279742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 46/246 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 71/181 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 62/278 reads (22%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- ABLIM2 | c.1516C>T p.R506* (on ENST00000341937 / NM_001130084.2; = p.Q455* on NM_032432.5) | Nonsense Mutation (SNP) | VAF 60/136 reads (44%) | catalogued as COSV56408599; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/204 reads (18%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAR | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs779004315, CM103757, COSV52719506; called by muse, mutect2, varscan2
- ADGRF4 | c.1627T>C p.Y543H | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51956202; called by muse, mutect2
- AIFM2 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57160341; called by muse, mutect2, varscan2
- AKAP13 | c.2480G>A p.G827D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.041); catalogued as COSV63466301; called by muse, mutect2, varscan2
- ALDH16A1 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53195908; called by muse, mutect2
- ALPK3 | c.4883C>T p.P1628L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs371706327, COSV51935895; called by muse, mutect2, varscan2
- ALS2 | c.3517del p.E1173Kfs*35 | Frame Shift Del (DEL) | VAF 347/984 reads (35%) | catalogued as rs1317051984; called by mutect2, pindel, varscan2
- ANO4 | c.2546C>T p.S849L (on ENST00000392977 / NM_001286615.2; = p.S814L on NM_178826.4) | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376008571, COSV54610752; called by muse, mutect2
- AP1S1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61760890; called by muse, mutect2, varscan2
- AQP12A | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774372497, COSV61836788; called by muse, mutect2, varscan2
- ARHGEF12 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63106696; called by muse, mutect2, varscan2
- ATP13A1 | c.3487G>A p.V1163M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1458867201, COSV52290062; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs772363145; called by mutect2, pindel
- ATP6V0E2 | c.173C>T p.A58V (on ENST00000425642; = p.A107V on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs774810930, COSV70416809; called by muse, mutect2, varscan2
- BAZ1B | c.2822G>A p.C941Y | Missense Mutation (SNP) | VAF 106/520 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1554571691, COSV59993427; called by muse, mutect2, varscan2
- BPIFB1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.102); catalogued as rs755296001, COSV53608168; called by muse, mutect2, varscan2
- BRIP1 | c.959G>C p.S320T | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV52006239; called by muse, mutect2, varscan2
- C10orf71 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV60511171; called by muse, mutect2
- C15orf40 | c.457dup p.T153Nfs*16 | Frame Shift Ins (INS) | VAF 33/155 reads (21%) | catalogued as rs751372654; called by mutect2, varscan2
- C1orf74 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs1339199104, COSV50558076; called by muse, mutect2, varscan2
- C22orf31 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV53311062; called by muse, mutect2
- C6orf15 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363195199, COSV52539636; called by muse, mutect2
- CACNA1B | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200880829, COSV53142346; called by muse, mutect2, varscan2
- CACNA1E | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 170/522 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1228711500, COSV62412279; called by muse, mutect2, varscan2
- CCDC142 | c.1021+2T>C p.X341_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | catalogued as COSV51779305; called by muse, mutect2, varscan2
- CCDC50 | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.346); catalogued as rs1253433440, COSV66669261; called by muse, mutect2, varscan2
- CCNQ | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV52345301, COSV99367983; called by muse, mutect2, varscan2
- CD46 | c.735del p.K245Nfs*53 | Frame Shift Del (DEL) | VAF 87/301 reads (29%) | catalogued as rs1343140692; called by mutect2, pindel, varscan2
- CD53 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 17/567 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV54762666; called by muse, mutect2
- CDADC1 | c.1221-1G>A p.X407_splice | Splice Site (SNP) | VAF 82/172 reads (48%) | catalogued as COSV51913051, COSV99212596; called by muse, mutect2, varscan2
- CDK18 | c.877C>T p.H293Y (on ENST00000506784 / NM_212503.3; = p.H263Y on NM_002596.4) | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63727617; called by muse, mutect2, varscan2
- CEBPE | c.566del p.P189Rfs*12 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV52829331; called by mutect2, varscan2
- CES3 | c.1629G>A p.W543* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV57594906, COSV57595436; called by muse, mutect2, varscan2
- CHAF1B | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58441234; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as rs751548647; called by mutect2, varscan2
- CLCN7 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775122102, COSV51972946; called by muse, mutect2, varscan2
- COL4A5 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1386149649, COSV60368691; called by muse, mutect2, varscan2
- COPA | c.2983G>T p.G995C | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as COSV54107765; called by muse, mutect2, varscan2
- COPS7A | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs146292223, COSV57527174; called by muse, mutect2, varscan2
- CRACD | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.578); catalogued as rs1450966409, COSV51728820; called by muse, mutect2, varscan2
- CSMD2 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV53947813; called by muse, mutect2, varscan2
- CSMD3 | c.2684G>A p.C895Y (on ENST00000297405 / NM_001363185.1; = p.C791Y on NM_052900.3) | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52280538, COSV99849998; called by muse, mutect2, varscan2
- CTCF | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 162/350 reads (46%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1567616147, COSV50500730; called by muse, mutect2, varscan2
- CUBN | c.1429T>C p.S477P | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.821); catalogued as COSV64724111; called by muse, mutect2, varscan2
- CUL3 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52368707; called by muse, mutect2
- CUL7 | c.2271G>T p.K757N | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54820702; called by muse, mutect2, varscan2
- CYBA | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs776963412, COSV55369074; called by muse, mutect2
- CYC1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1290121873, COSV59644867, COSV59644885; called by muse, mutect2, varscan2
- CYP46A1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV55896151; called by muse, mutect2
- CYP4F11 | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV56128903; called by muse, mutect2
- DCLK2 | c.1193A>T p.K398M | Missense Mutation (SNP) | VAF 77/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56210005; called by muse, mutect2, varscan2
- DCST1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs958801714, COSV55062127; called by muse, mutect2, varscan2
- DDX42 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 34/259 reads (13%) | catalogued as COSV63790989; called by muse, mutect2, varscan2
- DDX49 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765629684, COSV55358369; called by muse, mutect2, varscan2
- DENND4B | c.1851C>G p.H617Q | Missense Mutation (SNP) | VAF 368/606 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV63411218; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 35/224 reads (16%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DMBT1 | c.7481G>A p.C2494Y (on ENST00000338354 / NM_001377530.1; = p.C1737Y on NM_004406.3) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57551968; called by muse, mutect2, varscan2
- DNAH11 | c.8426C>T p.T2809M | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs781096429, COSV60973964; called by muse, mutect2, varscan2
- DNAH17 | c.3325G>T p.G1109C | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101102128; called by muse, mutect2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 46/248 reads (19%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.1037dup p.Q347Afs*6 | Frame Shift Ins (INS) | VAF 42/190 reads (22%) | catalogued as rs761292636; called by mutect2, varscan2
- DNPEP | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs774093656, COSV56111680; called by muse, mutect2, varscan2
- DOCK5 | c.4685del p.G1562Afs*28 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as COSV99376300; called by mutect2, pindel, varscan2
- DUOX1 | c.4568del p.P1523Lfs*3 | Frame Shift Del (DEL) | VAF 37/213 reads (17%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- EFCAB1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 159/382 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.976); catalogued as rs762907312, COSV50619538; called by muse, mutect2, varscan2
- EPHX1 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV55303169; called by muse, mutect2, varscan2
- EPN1 | c.1522G>A p.G508R (on ENST00000270460 / NM_001321263.1; = p.G482R on NM_013333.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs914959593, COSV50036071; called by muse, mutect2, varscan2
- FAM20B | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV55381862; called by muse, mutect2, varscan2
- FAT3 | c.11963C>T p.S3988L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780289899, COSV53107917; called by muse, mutect2, varscan2
- FAT4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.644); catalogued as rs372170599, COSV67896259; called by muse, mutect2, varscan2
- FBXO24 | c.962del p.G321Efs*69 (on ENST00000241071 / NM_033506.3; = p.G359Efs*69 on NM_012172.5) | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as rs1412286983; called by mutect2, pindel, varscan2
- FBXW5 | c.1049A>T p.Y350F | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56403835; called by muse, mutect2, varscan2
- FERMT1 | c.1737del p.D580Mfs*11 | Frame Shift Del (DEL) | VAF 67/399 reads (17%) | catalogued as rs1330809290; called by mutect2, pindel, varscan2
- FEZF2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51864194; called by muse, mutect2, varscan2
- FLG | c.11675G>T p.R3892L | Missense Mutation (SNP) | VAF 173/524 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs372348813, COSV64242241; called by muse, mutect2, varscan2
- FLVCR1 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV65324249; called by muse, mutect2
- FNDC1 | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV51945437; called by muse, mutect2, varscan2
- FNDC4 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs759239659, COSV53022369; called by muse, mutect2, varscan2
- FOXD4 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs748617570, COSV58702201; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FUT5 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144634186; called by muse, mutect2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 102/208 reads (49%) | catalogued as rs756304971; called by mutect2, varscan2
- GABRA5 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59484243; called by muse, mutect2, varscan2
- GAGE1 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 74/601 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs782550992, COSV67747855; called by muse, varscan2
- GALNT17 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs761079507, COSV61183056; called by muse, mutect2, varscan2
- GCM1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 151/720 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52523545; called by muse, mutect2, varscan2
- GCM1 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 149/718 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52523559; called by muse, mutect2, varscan2
- GNA13 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368032781, COSV71475115; called by muse, mutect2, varscan2
- GNB5 | c.257G>A p.R86Q (on ENST00000261837 / NM_016194.4; = p.R44Q on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs776406670, COSV55900685; called by muse, mutect2, varscan2
- GPATCH3 | c.974T>C p.I325T | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64652540; called by muse, mutect2, varscan2
- GPATCH8 | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs753448605, COSV59197308; called by muse, mutect2, varscan2
- GPR158 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.508); catalogued as rs749413527, COSV66278957; called by muse, mutect2, varscan2
- GPX3 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1196436522, COSV59303850; called by muse, mutect2, varscan2
- GTF2F2 | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as COSV61242118; called by muse, mutect2, varscan2
- H2BC1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 40/1058 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs142382084; called by muse, mutect2
- H6PD | c.1463_1464insA p.L489Sfs*8 | Frame Shift Ins (INS) | VAF 11/51 reads (22%) | catalogued as COSV101072460; called by mutect2, pindel, varscan2
- HCRTR2 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs866820748, COSV63797066; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HECTD1 | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs367653309; called by muse, mutect2, varscan2
- HELT | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867105445, COSV58820394; called by muse, mutect2, varscan2
- HIPK4 | c.1382T>C p.I461T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV52524657; called by muse, mutect2, varscan2
- HIRA | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54273300; called by muse, mutect2, varscan2
- HLX | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65044677; called by muse, varscan2
- ICE2 | c.1709G>T p.S570I | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV55029518, COSV55033418; called by muse, mutect2, varscan2
- IL13RA2 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 6/198 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54567091; called by muse, mutect2
- IL17RB | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV55473838; called by muse, mutect2, varscan2
- IMPG1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 36/163 reads (22%) | catalogued as COSV64060643; called by muse, mutect2, varscan2
- INTS4 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71090987; called by muse, mutect2
- ITCH | c.2399G>A p.R800H (on ENST00000262650 / NM_001257137.3; = p.R759H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/485 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs759593203, COSV52931952, COSV52933921; called by muse, mutect2, varscan2
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs1303173835; called by mutect2, pindel, varscan2
- KATNAL2 | c.343G>A p.D115N (on ENST00000356157 / NM_001353899.1; = p.D43N on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs370318400, COSV55295967; called by muse, mutect2, varscan2
- KCNJ8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV53717835; called by muse, mutect2
- KDM4D | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1555099539, COSV58633580; called by muse, mutect2
- KIAA0586 | c.1335T>A p.S445R (on ENST00000619416 / NM_001244190.2; = p.S460R on NM_014749.5) | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.076); catalogued as COSV54180736; called by muse, mutect2, varscan2
- KLK6 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745929255, COSV59566468; called by muse, mutect2, varscan2
- KMT2D | c.16330G>A p.E5444K | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1436698999, COSV56423925; called by muse, mutect2
- KRT3 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.246); catalogued as rs750421344, COSV58816744; called by muse, mutect2
- LCMT2 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59791425; called by muse, mutect2, varscan2
- LCN1 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV55019114; called by muse, mutect2, varscan2
- LINGO4 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as COSV64314106; called by muse, mutect2, varscan2
- LMBR1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs760685039, COSV62222582; called by muse, mutect2, varscan2
- LMF1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748153798, COSV51901028; called by muse, mutect2, varscan2
- LMOD3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376653017, COSV70456400; called by muse, mutect2, varscan2
- LRMDA | c.312C>T p.Y104= | Splice Region (SNP) | VAF 54/223 reads (24%) | catalogued as rs748106283, COSV65281464; called by muse, mutect2, varscan2
- LRRC30 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.723); catalogued as rs746658153, COSV67301387; called by muse, mutect2, varscan2
- LRRC37A2 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs370112456; called by muse, mutect2, varscan2
- LRRC47 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377537674; called by muse, mutect2
- MAGEL2 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs764155137, COSV58567986, COSV58568608; called by muse, mutect2, varscan2
- MAP2K4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 140/345 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs771926980, COSV62259715, COSV62259975; called by muse, mutect2, varscan2
- MAP4K3 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252160971, COSV55713408, COSV55716811; called by muse, mutect2, varscan2
- MCPH1 | c.1402dup p.T468Nfs*5 | Frame Shift Ins (INS) | VAF 39/197 reads (20%) | catalogued as rs768835889; called by mutect2, varscan2
- MFSD8 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.214); catalogued as COSV56552580; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 176/406 reads (43%) | catalogued as rs749903408; called by mutect2, varscan2
- MMP24 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); catalogued as rs369406481, COSV55772425; called by muse, mutect2, varscan2
- MORC1 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51727904; called by muse, mutect2, varscan2
- MRPL2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52435832; called by muse, mutect2, varscan2
- MRPS9 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 50/476 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs149588889; called by muse, mutect2, varscan2
- MRS2 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); catalogued as COSV51235247; called by muse, mutect2
- MUC15 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 134/587 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV55556562; called by muse, mutect2, varscan2
- MUC16 | c.19919G>A p.G6640D | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV67484572; called by muse, mutect2, varscan2
- MUC5AC | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); catalogued as rs750263003, COSV62254122; called by muse, varscan2
- MUC5B | c.9596C>T p.T3199M | Missense Mutation (SNP) | VAF 114/730 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs371217175; called by muse, mutect2, varscan2
- MX2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58098696; called by muse, mutect2, varscan2
- MYBL2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as rs1421774290, COSV53832670; called by muse, mutect2
- MYH15 | c.3071T>C p.M1024T | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56317118; called by muse, mutect2, varscan2
- MYO3A | c.4004A>G p.Q1335R | Missense Mutation (SNP) | VAF 176/401 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.055); catalogued as COSV56343819; called by muse, mutect2, varscan2
- MYO7B | c.5116C>A p.L1706I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67350593; called by muse, mutect2, varscan2
- MYO7B | c.6059C>A p.P2020H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61444411; called by muse, mutect2, varscan2
- MYO9B | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs945901127, COSV68281827, COSV68281985; called by muse, mutect2
- NALCN | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); catalogued as rs1393029318, COSV51927745, COSV51956861; called by muse, mutect2, varscan2
- NCOA6 | c.5189G>A p.R1730Q | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs375266173; called by muse, mutect2, varscan2
- NEFH | c.2467C>A p.P823T | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV60219709; called by muse, mutect2, varscan2
- NEU2 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs779779448, COSV52092814; called by muse, mutect2, varscan2
- NEUROG3 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs770935946, COSV54343579; called by mutect2, varscan2
- NFKB2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as COSV50041887; called by muse, mutect2
- NKRF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as rs763380713, COSV100441847, COSV58662541; called by muse, mutect2, varscan2
- NR2F1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1385776531, COSV59067631; called by muse, mutect2
- ODF2L | c.1619T>C p.M540T (on ENST00000317336; = p.M524T on NM_020729.3) | Missense Mutation (SNP) | VAF 81/469 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54017447; called by muse, mutect2, varscan2
- OR10AD1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59612961; called by muse, mutect2, varscan2
- OR10P1 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV59008250; called by muse, mutect2, varscan2
- OR2C3 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63575905; called by muse, mutect2, varscan2
- OR2L3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs765931236, COSV63455451; called by muse, mutect2
- PAFAH1B1 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 30/698 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV101250346, COSV68210531; called by muse, mutect2
- PAMR1 | c.1572G>T p.L524F (on ENST00000619888 / NM_001001991.3; = p.L541F on NM_015430.4) | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53515504; called by muse, mutect2, varscan2
- PCDHA3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1562179138, COSV100973711, COSV65370192; called by muse, mutect2, varscan2
- PCOLCE | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV53828645; called by muse, mutect2, varscan2
- PDE4DIP | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57720333; called by muse, mutect2, varscan2
- PKP1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771050304, COSV55824224; called by muse, mutect2, varscan2
- PLA1A | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV56332675; called by muse, mutect2, varscan2
- PLAGL1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52788439; called by muse, mutect2
- PMS2 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV56223384; called by muse, mutect2, varscan2
- PNCK | c.437C>T p.T146M (on ENST00000340888 / NM_001366975.1; = p.T229M on NM_001039582.3) | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs782141197, COSV61745063; called by muse, mutect2, varscan2
- POLR1A | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1487438296, COSV55697801; called by muse, varscan2
- PPP1R7 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV52146497; called by muse, mutect2, varscan2
- PPP4R2 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV55597380; called by muse, mutect2, varscan2
- PPP6R1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV69800463; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | catalogued as rs760446387; called by mutect2, varscan2
- PSD2 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs202188936; called by muse, mutect2, varscan2
- PSG5 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.094); catalogued as rs200424493; called by muse, mutect2
- PTEN | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 104/451 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64297602, COSV64303463, COSV64307402; called by muse, mutect2, varscan2
- PTGES2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs745728595, COSV52969166; called by muse, mutect2, varscan2
- PTGIS | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147983323; called by muse, mutect2, varscan2
- PTHLH | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52366502; called by muse, mutect2, varscan2
- PTPRB | c.2558T>C p.L853P | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54250157; called by muse, mutect2, varscan2
- PTPRC | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1173201390, COSV61418876; called by muse, mutect2, varscan2
- PTPRS | c.3310A>G p.S1104G | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV53632535; called by muse, mutect2, varscan2
- PWWP3A | c.76G>A p.A26T (on ENST00000627377; = p.A25T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/702 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs779704198, COSV60902516; called by muse, mutect2
- PYDC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs377601641; called by muse, mutect2, varscan2
- RBL1 | c.847-1G>T p.X283_splice | Splice Site (SNP) | VAF 9/259 reads (3%) | catalogued as COSV60332654, COSV60332676; called by muse, mutect2
- RBM42 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52898830; called by muse, mutect2, varscan2
- RECQL5 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769730810, COSV58644934; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RRP12 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145670609; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 27/169 reads (16%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SALL4 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53855163; called by muse, mutect2, varscan2
- SBF1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62369840; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 354/934 reads (38%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCRN1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1420336941, COSV54133016; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 68/306 reads (22%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs751191303; called by mutect2, varscan2
- SEMA7A | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1375132805, COSV56091861; called by muse, mutect2, varscan2
- SEPTIN10 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs761673341, COSV61781536; called by muse, mutect2
- SETD6 | c.580C>T p.P194S (on ENST00000219315 / NM_001160305.4; = p.P170S on NM_024860.3) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398409276, COSV50750228; called by muse, mutect2
- SETMAR | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as rs967760150, COSV62781298; called by muse, mutect2, varscan2
- SFRP2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 217/471 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as COSV56838150, COSV56838365; called by muse, mutect2, varscan2
- SIRT2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs926292218, COSV50874936; called by muse, mutect2, varscan2
- SLC10A1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs148905100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC15A1 | c.1212C>G p.N404K | Missense Mutation (SNP) | VAF 77/525 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.597); catalogued as COSV64733111; called by muse, mutect2, varscan2
- SLC26A3 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752002517, COSV60641992; called by muse, mutect2, varscan2
- SLC26A7 | c.1141-1G>A p.X381_splice | Splice Site (SNP) | VAF 74/478 reads (15%) | catalogued as COSV52601773; called by muse, mutect2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 28/174 reads (16%) | catalogued as rs760089491; called by mutect2, varscan2
- SLFN5 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs748278919, COSV55482851; called by muse, mutect2
- SND1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as COSV61247083; called by muse, mutect2, varscan2
- SNX27 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 369/1249 reads (30%) | catalogued as COSV64326071; called by muse, mutect2, varscan2
- SPTBN1 | c.5437G>A p.D1813N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765879123, COSV61685113; called by muse, mutect2, varscan2
- STRBP | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 147/311 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62119686; called by muse, mutect2, varscan2
- STXBP5L | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs746783421, COSV56499033; called by muse, mutect2, varscan2
- SULF2 | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV63419161; called by muse, mutect2, varscan2
- TAF1L | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 386/883 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299548601, COSV54266968, COSV54267258; called by muse, mutect2, varscan2
- TANC2 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV67339672; called by muse, mutect2
- TANGO2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as COSV59294871; called by muse, mutect2, varscan2
- TBC1D16 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60480384; called by muse, mutect2, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 26/155 reads (17%) | catalogued as rs757209781; called by pindel, varscan2
- TC2N | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs377688531; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 29/123 reads (24%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TEAD4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375587017; called by muse, mutect2, varscan2
- TEP1 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs993984452, COSV52995947; called by muse, mutect2, varscan2
- TET1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as rs761821309, COSV65383402; called by muse, mutect2, varscan2
- TEX2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.758); catalogued as rs782338359, COSV51984638; called by muse, mutect2, varscan2
- TG | c.3226A>T p.T1076S | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55089927; called by muse, mutect2, varscan2
- TLR8 | c.670C>A p.L224I (on ENST00000218032 / NM_138636.5; = p.L242I on NM_016610.4) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54319835; called by muse, mutect2, varscan2
- TMEM132D | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV70607402; called by muse, mutect2, varscan2
- TPM3 | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 156/511 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV55138537; called by muse, mutect2, varscan2
- TPP2 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 19/534 reads (4%) | catalogued as rs1419487180, COSV65750931; called by muse, mutect2
- TRANK1 | c.4288G>A p.V1430M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777724026, COSV57153436; called by muse, mutect2, varscan2
- TSNAXIP1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as rs779027930, COSV54651569; called by mutect2, varscan2
- TSSK1B | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs747955728, COSV66815865; called by muse, mutect2, varscan2
- TTC38 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66844921; called by muse, mutect2, varscan2
- TUBA1B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs1224745314, COSV60138164; called by muse, mutect2
- UBR4 | c.12121G>A p.A4041T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751511607, COSV64396410; called by muse, mutect2, varscan2
- UBR5 | c.6997C>T p.R2333* | Nonsense Mutation (SNP) | VAF 40/758 reads (5%) | catalogued as COSV55288277, COSV55296428; called by muse, mutect2
- UFL1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 48/632 reads (8%) | catalogued as rs1421340267, COSV65150506, COSV65150752; called by muse, mutect2
- UNC79 | c.7864G>T p.E2622* (on ENST00000393151 / NM_001346218.2; = p.E2445* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 37/208 reads (18%) | catalogued as COSV56404535; called by muse, mutect2, varscan2
- USHBP1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs759256700, COSV53104497; called by muse, mutect2, varscan2
- USP28 | c.497dup p.N166Kfs*9 | Frame Shift Ins (INS) | VAF 184/535 reads (34%) | catalogued as rs36030648; called by mutect2, pindel, varscan2
- WDR18 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs761796670, COSV52123097; called by muse, mutect2, varscan2
- WDTC1 | c.1381G>T p.G461W (on ENST00000319394 / NM_001276252.2; = p.G460W on NM_015023.5) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV60089841; called by muse, mutect2, varscan2
- WFS1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs144993516, CM165566; called by muse, mutect2, varscan2
- XIAP | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 9/293 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449553232, COSV63023501; called by muse, mutect2
- XRCC5 | c.2146G>T p.A716S | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.08); catalogued as COSV67534860, COSV67537512; called by muse, mutect2
- YTHDF1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV64833727; called by muse, mutect2
- ZAN | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61813925; called by muse, mutect2, varscan2
- ZBED1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100585500; called by muse, mutect2
- ZBTB40 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV65146196; called by muse, mutect2, varscan2
- ZFP28 | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV56737547; called by muse, mutect2, varscan2
- ZHX1 | c.1530del p.K510Nfs*31 | Frame Shift Del (DEL) | VAF 56/268 reads (21%) | catalogued as rs1563809035; called by mutect2, pindel, varscan2
- ZMYND11 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1275904257, COSV59076391; called by muse, mutect2, varscan2
- ZNF423 | c.1691C>T p.T564M (on ENST00000563137 / NM_001379286.1; = p.T556M on NM_015069.4) | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs573032120, COSV52190399; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs760397907; called by mutect2, pindel, varscan2
- ZSWIM8 | c.3493C>T p.R1165* (on ENST00000605216 / NM_001242487.2; = p.R1170* on NM_015037.3) | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as rs1320083360, COSV55214834; called by muse, mutect2, varscan2
- ADAM21 | c.1005del p.F335Lfs*9 | Frame Shift Del (DEL) | VAF 48/222 reads (22%) | called by mutect2, varscan2
- CCDC112 | c.909del p.K303Nfs*12 | Frame Shift Del (DEL) | VAF 92/562 reads (16%) | called by mutect2, pindel, varscan2
- CEP63 | c.2080_2081del p.K694Dfs*13 | Frame Shift Del (DEL) | VAF 149/392 reads (38%) | called by mutect2, pindel, varscan2
- CIC | c.1526del p.P509Hfs*14 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by pindel, varscan2
- CIC | c.1553del p.P518Rfs*5 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- CIC | c.4281del p.K1428Rfs*26 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, varscan2
- CLSTN2 | c.419del p.K140Sfs*11 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, varscan2
- CNTNAP4 | c.2492del p.L831* | Frame Shift Del (DEL) | VAF 78/441 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3335_3336del p.F1112Sfs*7 (on ENST00000297405 / NM_001363185.1; = p.F1008Sfs*7 on NM_052900.3) | Frame Shift Del (DEL) | VAF 39/211 reads (18%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 42/228 reads (18%) | called by mutect2, pindel, varscan2
- DOP1A | c.1876dup p.A626Gfs*8 | Frame Shift Ins (INS) | VAF 25/187 reads (13%) | called by mutect2, varscan2
- DVL2 | c.1736del p.G579Afs*102 | Frame Shift Del (DEL) | VAF 38/75 reads (51%) | called by mutect2, pindel, varscan2
- FAM135B | c.3898dup p.T1300Nfs*7 | Frame Shift Ins (INS) | VAF 155/368 reads (42%) | called by mutect2, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 92/480 reads (19%) | called by mutect2, varscan2
- FLNB | c.7665del p.C2556Afs*6 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel, varscan2
- FMR1 | c.899dup p.N300Kfs*20 | Frame Shift Ins (INS) | VAF 247/676 reads (37%) | called by mutect2, pindel, varscan2
- FRMD7 | c.26del p.L9Wfs*22 | Frame Shift Del (DEL) | VAF 107/283 reads (38%) | called by mutect2, pindel, varscan2
- GANAB | c.1694del p.G565Afs*23 | Frame Shift Del (DEL) | VAF 17/155 reads (11%) | called by mutect2, pindel, varscan2
- IGSF3 | c.3405del p.I1136Sfs*58 (on ENST00000369486 / NM_001007237.3; = p.I1156Sfs*58 on NM_001542.4) | Frame Shift Del (DEL) | VAF 130/666 reads (20%) | called by mutect2, varscan2
- KCNG4 | c.200del p.G67Afs*16 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- LIN54 | c.200_201del p.T67Sfs*4 | Frame Shift Del (DEL) | VAF 334/1066 reads (31%) | called by pindel, varscan2
- MICAL3 | c.5116del p.R1706Afs*24 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- MTIF2 | c.1739_1740del p.N580Sfs*14 | Frame Shift Del (DEL) | VAF 15/179 reads (8%) | called by mutect2, pindel
- MUC2 | c.3875G>A p.S1292N | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- NAB2 | c.547dup p.R183Pfs*36 | Frame Shift Ins (INS) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- NLRC5 | c.4967_4968del p.E1656Vfs*95 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | called by pindel, varscan2
- NSUN7 | c.118dup p.T40Nfs*34 | Frame Shift Ins (INS) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- PKDREJ | c.4755dup p.A1586Cfs*4 | Frame Shift Ins (INS) | VAF 80/432 reads (19%) | called by mutect2, pindel, varscan2
- PLCE1 | c.4489del p.M1497Wfs*14 | Frame Shift Del (DEL) | VAF 38/236 reads (16%) | called by mutect2, pindel, varscan2
- PTPRK | c.2327del p.K776Rfs*19 (on ENST00000368215 / NM_001291984.2; = p.K777Rfs*19 on NM_002844.4) | Frame Shift Del (DEL) | VAF 53/378 reads (14%) | called by pindel, varscan2
- RCC1 | c.704del p.G235Efs*6 | Frame Shift Del (DEL) | VAF 34/224 reads (15%) | called by mutect2, pindel, varscan2
- RINL | c.546del p.R183Gfs*31 (on ENST00000591812 / NM_001195833.2; = p.R69Gfs*31 on NM_198445.4) | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- RYR1 | c.746del p.G249Efs*16 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- SASS6 | c.567del p.K189Nfs*4 | Frame Shift Del (DEL) | VAF 111/531 reads (21%) | called by mutect2, varscan2
- SERTAD2 | c.878del p.P293Qfs*40 | Frame Shift Del (DEL) | VAF 42/212 reads (20%) | called by mutect2, pindel, varscan2
- SHOX2 | c.533del p.G178Afs*31 (on ENST00000441443 / NM_006884.3; = p.G202Afs*31 on NM_003030.4) | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.20del p.P7Qfs*2 | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | called by mutect2, pindel, varscan2
- SLX4 | c.3166del p.L1056Cfs*60 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- SSH2 | c.1872del p.M625Cfs*32 | Frame Shift Del (DEL) | VAF 63/161 reads (39%) | called by mutect2, pindel, varscan2
- TAS2R14 | c.383del p.K128Rfs*9 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- UBAP2 | c.2401del p.V801Cfs*11 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- UBTF | c.475-3del | Splice Region (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- ZC3H14 | c.921del p.K307Nfs*48 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, varscan2
- ADARB2 | c.1665C>T p.C555= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV67233285; called by muse, mutect2, varscan2
- ALAS1 | c.1389C>T p.T463= | Silent (SNP) | VAF 49/255 reads (19%) | catalogued as rs770294028, COSV59629298; called by muse, mutect2, varscan2
- ANKRD17 | c.1671A>T p.G557= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV58226110; called by muse, mutect2, varscan2
- CACNA1E | c.3843C>T p.C1281= | Silent (SNP) | VAF 51/421 reads (12%) | catalogued as rs373094161; called by muse, mutect2, varscan2
- CAMKK1 | c.1386G>A p.P462= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs148525822; called by muse, mutect2, varscan2
- CDPF1 | c.147C>A p.P49= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV53080760; called by muse, mutect2
- CDX2 | c.804C>T p.P268= | Silent (SNP) | VAF 96/213 reads (45%) | catalogued as COSV66829824; called by muse, mutect2, varscan2
- CNOT4 | c.969G>T p.R323= (on ENST00000315544 / NM_001190848.1; = p.R320= on NM_013316.4) | Silent (SNP) | VAF 310/687 reads (45%) | catalogued as COSV59657387; called by muse, mutect2, varscan2
- CSMD2 | c.10275G>A p.A3425= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs759844060, COSV53902268; called by muse, mutect2, varscan2
- CTAGE1 | c.411G>A p.A137= | Silent (SNP) | VAF 86/403 reads (21%) | catalogued as rs778256680, COSV66943594; called by muse, mutect2, varscan2
- CTR9 | c.3063G>A p.S1021= | Silent (SNP) | VAF 88/228 reads (39%) | catalogued as rs182230438, COSV63727850; called by muse, mutect2, varscan2
- CWF19L2 | c.504A>G p.S168= | Silent (SNP) | VAF 162/412 reads (39%) | catalogued as COSV56518137; called by muse, mutect2, varscan2
- DACH1 | c.1662C>A p.P554= (on ENST00000619232 / NM_001366712.1; = p.P502= on NM_080759.6) | Silent (SNP) | VAF 151/356 reads (42%) | catalogued as COSV57514857; called by muse, mutect2, varscan2
- EIF3B | c.1791C>T p.N597= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as rs754459941, COSV62804433; called by muse, mutect2, varscan2
- ELP1 | c.1665G>A p.G555= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as rs558485897, COSV65899334; called by muse, mutect2
- ENG | c.156C>T p.G52= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV61228466; called by muse, mutect2, varscan2
- EPN1 | c.162G>A p.S54= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs753679070, COSV50042401; called by muse, mutect2, varscan2
- ERGIC1 | c.666G>A p.T222= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs771935390, COSV67129062; called by muse, mutect2
- ETS1 | c.615C>T p.Y205= | Silent (SNP) | VAF 141/313 reads (45%) | catalogued as COSV60096360; called by muse, mutect2, varscan2
- EXOC3 | c.243C>T p.D81= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs772047083, COSV59268248; called by muse, mutect2, varscan2
- EXTL3 | c.660G>A p.A220= | Silent (SNP) | VAF 8/195 reads (4%) | catalogued as rs1238726417, COSV55039826, COSV99593797; called by muse, mutect2
- EYA4 | c.876G>A p.A292= | Silent (SNP) | VAF 27/235 reads (11%) | catalogued as rs750099139, COSV62051188; called by muse, varscan2
- FMNL3 | c.1119A>G p.A373= | Silent (SNP) | VAF 22/500 reads (4%) | catalogued as COSV53306184; called by muse, mutect2
- FOXD4L4 | c.234C>T p.G78= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- FOXR1 | c.216A>G p.G72= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV57653399; called by muse, mutect2, varscan2
- FRYL | c.4329G>A p.V1443= | Silent (SNP) | VAF 8/223 reads (4%) | catalogued as rs1429907319, COSV51957688; called by muse, mutect2
- GGA1 | c.537C>A p.A179= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV57331388; called by muse, mutect2, varscan2
- GPR87 | c.651C>T p.A217= | Silent (SNP) | VAF 101/299 reads (34%) | catalogued as rs1315214980, COSV53464168; called by muse, mutect2, varscan2
- GRM1 | c.429C>T p.D143= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1043423177, COSV51252880; called by muse, mutect2, varscan2
- HOXD10 | c.165G>A p.P55= | Silent (SNP) | VAF 14/274 reads (5%) | catalogued as rs1438215691, COSV50898406; called by muse, mutect2
- HRH2 | c.396A>C p.P132= | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as COSV51575666; called by muse, mutect2, varscan2
- ITIH2 | c.2805C>T p.F935= | Silent (SNP) | VAF 89/212 reads (42%) | catalogued as rs1471155220, COSV64433543, COSV64433666; called by muse, mutect2, varscan2
- ITIH4 | c.342C>T p.S114= | Silent (SNP) | VAF 104/252 reads (41%) | catalogued as rs772784447, COSV56576651; called by muse, mutect2, varscan2
- KCNB2 | c.1443C>T p.S481= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs781284488, COSV73051604; called by muse, mutect2, varscan2
- KCNC1 | c.774C>T p.F258= | Silent (SNP) | VAF 175/457 reads (38%) | catalogued as rs759363166, COSV56397279, COSV99789140; called by muse, mutect2, varscan2
- KCNH6 | c.1485C>T p.C495= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs765272133, COSV59006656; called by muse, mutect2
- KCNJ4 | c.771G>A p.S257= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as rs575461087, COSV57858303; called by muse, mutect2, varscan2
- KMT2C | c.12150A>G p.S4050= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV51484766; called by muse, mutect2
- KMT2D | c.12159T>C p.T4053= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV56473907; called by muse, mutect2
- KRT7 | c.1038G>A p.A346= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs775241475, COSV100081775, COSV59332553; called by muse, mutect2, varscan2
- LRBA | c.6198G>A p.V2066= | Silent (SNP) | VAF 43/260 reads (17%) | catalogued as COSV63961841; called by muse, mutect2, varscan2
- LRCH2 | c.318C>T p.S106= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV57757505; called by muse, mutect2, varscan2
- MIA3 | c.5637A>G p.L1879= | Silent (SNP) | VAF 139/245 reads (57%) | catalogued as COSV60516446; called by muse, mutect2, varscan2
- MPO | c.1827G>A p.P609= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs781536912, COSV51859729; called by muse, mutect2, varscan2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- MUC4 | c.12732C>T p.S4244= | Silent (SNP) | VAF 81/404 reads (20%) | catalogued as COSV57797160; called by muse, mutect2, varscan2
- NBPF3 | c.1149C>T p.D383= | Silent (SNP) | VAF 47/226 reads (21%) | catalogued as COSV59062754; called by muse, mutect2, varscan2
- NCF4 | c.702C>T p.D234= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs745954906, COSV50620518; called by muse, mutect2, varscan2
- NEK10 | c.2874G>A p.L958= | Silent (SNP) | VAF 54/257 reads (21%) | catalogued as rs771583230, COSV55363390; called by muse, mutect2, varscan2
- NWD1 | c.1410G>A p.S470= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs749508047, COSV60340158; called by muse, mutect2, varscan2
- ODR4 | c.180C>A p.P60= | Silent (SNP) | VAF 197/580 reads (34%) | catalogued as COSV55218791; called by muse, mutect2, varscan2
- OSER1 | c.504C>T p.D168= | Silent (SNP) | VAF 32/237 reads (14%) | catalogued as rs756181259, COSV54854349; called by muse, mutect2, varscan2
- PCDHA9 | c.1287C>T p.D429= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs782046330, COSV65331159; called by muse, mutect2, varscan2
- PCIF1 | c.2094C>T p.S698= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs781462804, COSV59819484; called by muse, varscan2
- PEG3 | c.795C>T p.G265= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as COSV55643689; called by muse, mutect2
- PES1 | c.1377G>A p.E459= | Silent (SNP) | VAF 89/223 reads (40%) | catalogued as COSV58829483; called by muse, mutect2, varscan2
- PIK3CG | c.897C>T p.N299= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1220639059, COSV63247243, COSV63247651; called by muse, mutect2
- PRSS1 | c.297C>T p.Y99= | Silent (SNP) | VAF 141/400 reads (35%) | catalogued as rs373659879, COSV61196178; called by muse, mutect2, varscan2
- PUS7L | c.1944C>A p.P648= | Silent (SNP) | VAF 75/385 reads (19%) | catalogued as COSV61262688; called by muse, mutect2, varscan2
- RALB | c.375C>T p.V125= | Silent (SNP) | VAF 94/218 reads (43%) | catalogued as rs148143386; called by muse, mutect2, varscan2
- REPS2 | c.618G>A p.V206= | Silent (SNP) | VAF 122/298 reads (41%) | catalogued as COSV58179246; called by muse, mutect2, varscan2
- RGS11 | c.735C>T p.S245= (on ENST00000397770 / NM_183337.3; = p.S224= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as rs749289973, COSV51453666; called by muse, mutect2, varscan2
- RGS21 | c.15C>T p.C5= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as COSV69883498, COSV69883676; called by muse, mutect2
- RIC8A | c.231C>T p.R77= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV57316061; called by muse, mutect2, varscan2
- RNF146 | c.921C>A p.S307= (on ENST00000368314 / NM_001242850.2; = p.S306= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 64/320 reads (20%) | catalogued as COSV58933764; called by muse, mutect2, varscan2
- RNF214 | c.2008C>T p.L670= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV56118681; called by muse, mutect2
- RPS6KC1 | c.2871C>A p.S957= | Silent (SNP) | VAF 107/843 reads (13%) | catalogued as COSV65302016; called by muse, mutect2, varscan2
- SIGLEC12 | c.9G>A p.L3= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV52464018; called by muse, mutect2
- SIPA1L1 | c.3354C>T p.D1118= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs778906238, COSV62172662; called by muse, mutect2, varscan2
- SLC9A6 | c.1467C>T p.T489= | Silent (SNP) | VAF 237/588 reads (40%) | catalogued as rs782672631, COSV65788470; called by muse, mutect2, varscan2
- SLITRK5 | c.2238C>T p.G746= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV61525307; called by muse, mutect2, varscan2
- SMYD2 | c.957G>A p.E319= | Silent (SNP) | VAF 39/310 reads (13%) | catalogued as COSV65291568; called by muse, mutect2, varscan2
- SRGAP1 | c.2311C>T p.L771= | Silent (SNP) | VAF 51/342 reads (15%) | catalogued as COSV61901802; called by muse, mutect2, varscan2
- STARD10 | c.744G>A p.A248= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV58326596; called by muse, mutect2, varscan2
- SYT14 | c.1653G>A p.A551= | Silent (SNP) | VAF 43/347 reads (12%) | catalogued as rs371789098; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCTN1 | c.1755G>A p.P585= (on ENST00000551590 / NM_001173975.3; = p.P571= on NM_024549.6) | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as rs370246838; called by muse, varscan2
- TNS3 | c.2682C>T p.H894= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as rs775324309, COSV60796704; called by muse, mutect2
- TRIM25 | c.1395C>T p.T465= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs770136591, COSV57545283; called by muse, mutect2, varscan2
- TRPM1 | c.4330C>A p.R1444= | Silent (SNP) | VAF 99/209 reads (47%) | catalogued as COSV56630796, COSV56639929; called by muse, mutect2, varscan2
- VPS45 | c.679C>T p.L227= | Silent (SNP) | VAF 66/558 reads (12%) | catalogued as COSV64888746; called by muse, mutect2, varscan2
- WARS2 | c.387C>T p.C129= | Silent (SNP) | VAF 50/386 reads (13%) | catalogued as rs376072470; called by muse, mutect2, varscan2
- WHRN | c.1695C>T p.S565= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs558215535, COSV54330025; called by muse, mutect2, varscan2
- ZBTB20 | c.1548C>T p.P516= (on ENST00000474710 / NM_001164342.2; = p.P443= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs139463539, COSV61863347; called by muse, mutect2, varscan2
- ZNF532 | c.3615C>T p.C1205= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV60174980; called by muse, varscan2
- ACP1 | c.231+56C>T | Intron (SNP) | VAF 84/425 reads (20%) | catalogued as rs781441469, COSV55244985; called by muse, mutect2, varscan2
- ANK1 | c.5395-1114C>T | Intron (SNP) | VAF 18/35 reads (51%) | catalogued as rs565535918, COSV55900629; called by muse, mutect2
- DPF2 | c.-1G>T | 5'UTR (SNP) | VAF 30/382 reads (8%) | catalogued as COSV52889059; called by muse, mutect2
- MIR1-1HG-AS1 | n.737C>A | RNA (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- RAP1GAP | c.-101G>A | 5'UTR (SNP) | VAF 54/237 reads (23%) | catalogued as COSV51576411; called by muse, mutect2, varscan2
